Somatic mutation profile of tumor specimen MP2PRT-PAVAFT-TMP1-A (aliquot MP2PRT-PAVAFT-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVAFT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,256 days).
Specimen MP2PRT-PAVAFT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c64900c1-b29f-4d3a-9c55-5ea5668f9091.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAFT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAFT-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3448b1d-e80a-4a60-bfb0-eb4395138ea3

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 96/271 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CSMD2 | c.8537G>A p.R2846H | Missense Mutation (SNP) | VAF 188/437 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs775463572, COSV53879418; called by muse, mutect2, varscan2
- GREB1L | c.1894G>A p.G632R | Missense Mutation (SNP) | VAF 128/423 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as COSV52568197; called by muse, mutect2, varscan2
- MYO15A | c.3866C>T p.P1289L | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192483691, COSV52762367, COSV99234164; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIPK2B | c.356A>C p.K119T | Missense Mutation (SNP) | VAF 522/838 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ETV6 | c.395_396insTTACC p.F133Yfs*78 | Frame Shift Ins (INS) | VAF 107/291 reads (37%) | called by mutect2, pindel, varscan2
- OR5M8 | c.456G>A p.A152= | Silent (SNP) | VAF 152/380 reads (40%) | catalogued as rs761721814, COSV59116388; called by muse, mutect2, varscan2
